Somatic mutation profile of tumor specimen 0DJVPK from CCDI case PBBUVM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,230 days).
Specimen 0DJVPK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9aaa898-e125-4f05-b35a-4586abd6e402.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVP6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/405edfb3-2b9e-4b6d-8d1d-1cfe032724dc

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Splice Site 3, Silent 2, 3'UTR 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.6625G>A p.E2209K (on ENST00000367573 / NM_001205293.3; = p.E2166K on NM_000721.4) | Missense Mutation (SNP) | VAF 244/1062 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.358); catalogued as rs201030442; called by muse, mutect2, varscan2
- KBTBD4 | c.884_886dup p.P295dup | In Frame Ins (INS) | VAF 363/940 reads (39%) | catalogued as COSV58596732, COSV58597734, COSV58597899; called by mutect2, pindel, varscan2
- LRFN4 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 56/784 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs761099728; called by muse, mutect2
- RIF1 | c.4785A>G p.I1595M | Missense Mutation (SNP) | VAF 94/2055 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1559016981; called by muse, mutect2
- SLCO1A2 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 404/1887 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs745627320, COSV100262374, COSV56602664; called by muse, mutect2, varscan2
- ZSCAN20 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 367/790 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs578037564, COSV63681794; called by muse, mutect2, varscan2
- ADRB3 | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 324/773 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 54/1627 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 42/1388 reads (3%) | called by muse, mutect2
- GSTA4 | c.140-18_151del p.X47_splice | Splice Site (DEL) | VAF 454/1497 reads (30%) | called by mutect2, pindel, varscan2
- HHIP | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 309/2045 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP9 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 82/1558 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2
- RBM5 | c.409+1G>T p.X137_splice | Splice Site (SNP) | VAF 510/1059 reads (48%) | called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 74/1825 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 70/2090 reads (3%) | called by muse, mutect2
- TTC30B | c.249G>A p.L83= | Silent (SNP) | VAF 379/834 reads (45%) | catalogued as rs761197977; called by muse, mutect2, varscan2
- CHSY3 | c.-45C>A | 5'UTR (SNP) | VAF 42/142 reads (30%) | called by mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 62/1068 reads (6%) | called by muse, mutect2
- MRPL20 | c.276+86C>G | Intron (SNP) | VAF 145/311 reads (47%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 18/275 reads (7%) | called by muse, mutect2
- PCSK5 | c.2626+3495G>A | Intron (SNP) | VAF 563/1213 reads (46%) | catalogued as rs775968230; called by muse, mutect2, varscan2
- RASGRF1 | c.3462+35G>A | Intron (SNP) | VAF 352/685 reads (51%) | catalogued as rs1270574778, COSV100293903; called by muse, mutect2, varscan2
